Somatic mutation profile of tumor specimen TARGET-20-PATABB-04A (aliquot TARGET-20-PATABB-04A-01D) from TARGET case TARGET-20-PATABB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (652 days).
Specimen TARGET-20-PATABB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46371375-b578-4ca6-ac74-5f534662f8d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATABB-14A (Bone Marrow Normal), aliquot TARGET-20-PATABB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/076ef907-8f67-4822-9c76-3a902dce9a6d

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 3, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAPLN1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV57150052; called by muse, varscan2
- B3GNT7 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2
- FAM131A | c.851T>C p.L284P (on ENST00000310585; = p.L315P on NM_144635.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2
- ZBED9 | c.3514G>T p.A1172S | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- EEF1G | c.1233G>A p.T411= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs748064470; called by muse, mutect2, varscan2
- GJB7 | c.636A>G p.Q212= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- KLF16 | c.396G>A p.P132= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- NAT8L | c.705C>T p.F235= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs752594380, COSV59051635; called by muse, mutect2, varscan2
- OR5H15 | c.309C>A p.S103= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, varscan2
- SV2B | c.402C>A p.P134= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as COSV100370572; called by muse, mutect2
- CLCNKB | c.*3C>T | 3'UTR (SNP) | VAF 83/571 reads (15%) | catalogued as rs372433643; called by muse, mutect2, varscan2
